Gene-level copy-number profile of tumor specimen TCGA-F5-6464-01A from TCGA case TCGA-F5-6464, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 77.1 years (28,168 days).
Specimen TCGA-F5-6464-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.72029f21-a40c-42f9-80ea-4c3d9d971279.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-F5-6464-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/53de5123-7125-4aa2-9fba-ac71b3761a63

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 1,908; copy number 3: 1,266; copy number 4: 31,659; copy number 5: 5,387; copy number 6: 9,092; copy number 7: 3,329; copy number 8: 804; copy number 9: 6,108; copy number 10: 11; copy number 12: 252.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-F5-6464-01A-11D-1732-01): tumor purity 0.47, ploidy 2.52, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 6,371 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:117,596,832–118,264,489, 11 genes, copy number 10: AL157902.1, TENT5C, VDAC2P3, AL390877.1, AL390877.2, PNRC2P1, GDAP2, WDR3, SPAG17, AL391557.1, RNA5SP56.
- chr1:149,842,875–154,155,116, 252 genes, copy number 12 (within-gene range 7–12) (broad region; genes not listed).
- chr7:40,135,005–40,860,763, 1 gene, copy number 9 (within-gene range 8–9): SUGCT.
- chr7:40,538,127–110,534,757, 1,324 genes, copy number 9 (broad region; genes not listed).
- chr7:110,662,644–111,562,517, 1 gene, copy number 9 (within-gene range 6–9): IMMP2L.
- chr7:111,091,006–159,233,377, 962 genes, copy number 9 (broad region; genes not listed).
- chr8:82,862,779–145,066,685, 976 genes, copy number 9 (broad region; genes not listed).
- chr13:18,467,172–67,379,994, 816 genes, copy number 9 (broad region; genes not listed).
- chr13:68,025,839–114,337,626, 570 genes, copy number 9 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
